Somatic mutation profile of tumor specimen TCGA-EL-A3GO-01A (aliquot TCGA-EL-A3GO-01A-11D-A202-08) from TCGA case TCGA-EL-A3GO, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 31.8 years (11,604 days).
Specimen TCGA-EL-A3GO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 615b6b89-99b9-4ea7-95ad-e1e70993fd85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3GO-10A (Blood Derived Normal), aliquot TCGA-EL-A3GO-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e20c4aa6-b167-4378-baaf-49e89033eaa4

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5428G>C p.D1810H | Missense Mutation (SNP) | VAF 99/280 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58615443, COSV58615662, COSV58615890; called by muse, mutect2, varscan2
- ARHGEF6 | c.1317G>T p.W439C | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51687334; called by muse, mutect2, varscan2
- CCDC24 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs777434104, COSV58842351; called by muse, mutect2
- CSMD2 | c.8570T>C p.M2857T | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV53876738; called by muse, mutect2, varscan2
- HEATR6 | c.1311A>T p.K437N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV51743560; called by muse, mutect2, varscan2
- OR51F1 | c.918A>T p.K306N | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV58578735; called by muse, mutect2, varscan2
- STAC2 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 91/267 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs370925083; called by muse, mutect2, varscan2
- DICER1 | c.1128_1132del p.K376Nfs*11 | Frame Shift Del (DEL) | VAF 53/160 reads (33%) | called by mutect2, pindel, varscan2
